Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAGT, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAGT-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; nonseminoma (MT 80%, YST 20%, osteoclastic giant cells in the YST-component); tumor diameter 6 cm; tumor confined to testis; angio-invasion present; invasion of rete testis present.

Date of procurement (= date of orchidectomy):

ICD 03

Mixed germ cell tumor
9085/3
Site: @ Testis NOS
C62.9
JW 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 8cba5f2f-4a81-4889-8f9c-e37e61294433 (TCGA-2G-AAGT.82E47665-5803-4689-BF3E-DC8670808C92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).